Somatic mutation profile of tumor specimen MP2PRT-PAVYYP-TMP1-A (aliquot MP2PRT-PAVYYP-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVYYP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,897 days).
Specimen MP2PRT-PAVYYP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22db492d-a69a-4df9-b2f0-0b75a6b22ec2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYYP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYYP-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/174c96df-5fd2-4618-9863-84357652a136

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAF1B | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 119/390 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754039374; called by muse, mutect2, varscan2
- COLGALT1 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 157/338 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99395097; called by muse, mutect2, varscan2
- CXorf58 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV64858744; called by muse, varscan2
- KBTBD13 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 36/818 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs775442274; called by muse, mutect2
- LRRC9 | c.2086A>T p.I696F | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs779939587; called by muse, mutect2, varscan2
- OR1C1 | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 65/350 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as rs750166927; called by muse, mutect2, varscan2
- OTUD6A | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 339/360 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57972709; called by muse, mutect2, varscan2
- SEC24A | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 12/336 reads (4%) | catalogued as COSV59746926; called by muse, mutect2
- CCDC178 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2
- UGT8 | c.1014A>G p.I338M | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2
- GLA | c.573G>C p.L191= | Silent (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- IGF2R | c.4326C>T p.D1442= | Silent (SNP) | VAF 54/630 reads (9%) | catalogued as rs780426967; called by muse, mutect2
- KRT1 | c.1683C>T p.S561= | Silent (SNP) | VAF 325/822 reads (40%) | catalogued as rs779551366, COSV52866594; called by mutect2, varscan2
- LOX | c.48C>T p.C16= | Silent (SNP) | VAF 55/636 reads (9%) | called by muse, mutect2
- NEB | c.3438C>T p.V1146= | Silent (SNP) | VAF 124/379 reads (33%) | catalogued as rs373118761; ClinVar: likely benign; called by muse, mutect2, varscan2
- PMEL | c.1755C>T p.I585= | Silent (SNP) | VAF 13/324 reads (4%) | called by muse, mutect2
